Somatic mutation profile of tumor specimen MP2PRT-PAVGZX-TMP1-A (aliquot MP2PRT-PAVGZX-TMP1-A-1-0-D-A83Q-36) from MP2PRT case MP2PRT-PAVGZX, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.2 years (426 days).
Specimen MP2PRT-PAVGZX-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fc1fb0bb-1fe8-4fa9-bd36-592683057ab7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVGZX-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVGZX-NB1-A-1-0-D-A83Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/54a068ab-0cc7-4e36-adf1-5961ea0e0212

The open-access MAF lists 7 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 2, Frame Shift Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.*22C>G | 3'UTR (SNP) | VAF 9/56 reads (16%) | catalogued as rs104894362, CM070970, COSV55666258, COSV56095155; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COPS5 | c.872C>T p.T291M | Missense Mutation (SNP) | VAF 124/268 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.15); catalogued as rs143525514; called by muse, mutect2, varscan2
- HLA-DQB2 | c.344G>A p.R115H | Missense Mutation (SNP) | VAF 34/510 reads (7%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs1386218739; called by muse, mutect2
- PFAS | c.3790G>C p.G1264R | Missense Mutation (SNP) | VAF 78/353 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58982421; called by muse, mutect2, varscan2
- PAX5 | c.562_578delinsGAAGGAAAAGGC p.T188Efs*53 | Frame Shift Del (DEL) | VAF 56/350 reads (16%) | called by pindel, varscan2*
- AFM | c.1572C>T p.F524= | Silent (SNP) | VAF 56/315 reads (18%) | called by muse, mutect2, varscan2
- IGHE | c.333G>A p.P111= | Silent (SNP) | VAF 32/293 reads (11%) | catalogued as rs781783809; called by muse, mutect2, varscan2
